Somatic mutation profile of tumor specimen TCGA-EL-A3ZH-01A (aliquot TCGA-EL-A3ZH-01A-31D-A23M-08) from TCGA case TCGA-EL-A3ZH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.9 years (15,685 days).
Specimen TCGA-EL-A3ZH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d1bea08-c904-44e2-8882-1fc62aae8e35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZH-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZH-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2763f1fe-0f1e-48a6-bf87-0297d4973437

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 59/125 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATXN2L | c.2764A>C p.T922P | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57373369; called by muse, mutect2, varscan2
- CCDC136 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV52801390, COSV52806508; called by muse, mutect2, varscan2
- CRACR2A | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1193390048, COSV52914678; called by muse, mutect2, varscan2
- KMT2A | c.4958A>C p.N1653T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV63288123; called by muse, mutect2
- BRCC3 | c.213T>A p.I71= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV57463022; called by muse, mutect2, varscan2
- MED15 | c.312G>C p.R104= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV53030698; called by muse, mutect2
